Gene-level copy-number profile of tumor specimen ALCH-ADOT-TTP1-A from ALCHEMIST case ALCH-ADOT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.5 years (19,171 days).
Specimen ALCH-ADOT-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e64895d0-68dd-41d9-ab5e-f8b42387a634.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADOT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/5a0b4e99-09d5-4aee-8f5e-6722fe56ca42

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 732; copy number 2: 57,437; copy number 3: 140; copy number 4: 41; copy number 5: 8; copy number 6: 3; copy number 7: 1; copy number 9: 5.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,326,201–2,326,693, 1 gene (within-gene range 0–2): AL589739.1.
- chr1:16,974,502–16,980,632, 2 genes (within-gene range 0–2): MFAP2, AL049569.2.
- chr1:228,555,793–228,621,565, 8 genes: RNA5SP19, RNA5SP162, RNA5S1, RNA5S2, RNA5S3, RNA5S4, RNA5S5, RNA5S6.
- chr2:238,138,668–238,152,947, 1 gene (within-gene range 0–2): KLHL30.
- chr2:240,435,663–240,468,076, 3 genes: GPC1, AC110619.1, MIR149.
- chr5:1,877,413–1,887,236, 2 genes: IRX4, IRX4-AS1.
- chr14:103,094,723–103,110,559, 2 genes: AL161669.1, EXOC3L4.
- chr15:19,964,666–19,968,352, 2 genes: IGHV1OR15-9, SLC20A1P3.
- chr17:29,560,547–29,567,037, 1 gene (within-gene range 0–2): ABHD15.
- chr17:29,566,052–29,573,157, 2 genes (within-gene range 0–2): TP53I13, AC104564.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:143,758,153–143,771,870, 1 gene, copy number 5: AC105219.3.
- chr11:1,947,278–2,001,470, 7 genes, copy number 5–9: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr22:18,178,038–18,345,899, 2 genes, copy number 5: FAM230D, GGTLC5P.
- chr22:18,615,581–18,653,617, 4 genes, copy number 5–7: Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2.
- chr22:18,733,914–18,757,906, 1 gene, copy number 6: FAM230E.
- chr22:21,300,990–21,325,042, 2 genes, copy number 5 (within-gene range 4–5): FAM230H, AP000552.2.

Autosomal genes at a single copy (total copy number 1): 721. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
